Somatic mutation profile of tumor specimen TCGA-CR-7398-01A (aliquot TCGA-CR-7398-01A-11D-2012-08) from TCGA case TCGA-CR-7398, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.3 years (19,468 days).
Specimen TCGA-CR-7398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 243b2452-5b93-43dd-a37d-f502bf654838.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7398-10A (Blood Derived Normal), aliquot TCGA-CR-7398-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74908a76-87ab-4bef-8fda-fe02b2da4457

The open-access MAF lists 379 somatic variants for this specimen: 280 protein-altering or splice-affecting, 88 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 88, Nonsense Mutation 21, Frame Shift Del 10, Splice Site 6, Frame Shift Ins 5, RNA 5, Intron 4, Splice Region 3, In Frame Del 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BUB1B | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 62/160 reads (39%) | catalogued as rs767213728, CM161677, COSV99806582; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>T p.R505L (on ENST00000281708 / NM_001349798.2; = p.R425L on NM_018315.5) | Missense Mutation (SNP) | VAF 37/66 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 23/34 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.5048C>T p.A1683V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1402394753, COSV64672655; called by muse, mutect2, varscan2
- ACADL | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99284538; called by muse, mutect2, varscan2
- ADAMTS19 | c.3089A>T p.K1030M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV50733806, COSV99176366; called by muse, mutect2, varscan2
- ADGRV1 | c.2151A>T p.L717F | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs749583333, COSV101315512; called by muse, mutect2, varscan2
- AKAP13 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100773163; called by muse, mutect2, varscan2
- AKAP14 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as rs1234554318, COSV100538226; called by muse, mutect2, varscan2
- ALAS2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM114505, COSV58188594, COSV58188642; called by muse, mutect2, varscan2
- AMER1 | c.3151G>A p.V1051M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100365337; called by muse, mutect2, varscan2
- AMY2A | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs145483775; called by muse, varscan2
- ANO1 | c.2801T>A p.F934Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100796926; called by muse, mutect2, varscan2
- AOX1 | c.1169T>C p.I390T | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV101021743; called by muse, mutect2, varscan2
- AOX1 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs139407288; called by muse, mutect2, varscan2
- AQP8 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762948461, COSV54845261; called by muse, mutect2, varscan2
- ARHGAP36 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV99357257; called by muse, mutect2, varscan2
- ARHGAP36 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV99357261; called by muse, mutect2, varscan2
- ARHGEF9 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99491378; called by muse, mutect2, varscan2
- ART4 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV99966821; called by muse, mutect2, varscan2
- ASRGL1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1352257014, COSV57125395; called by muse, mutect2, varscan2
- ATMIN | c.311A>T p.H104L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100214513; called by muse, mutect2, varscan2
- ATP1A2 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399834873, COSV63403362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.1668G>A p.M556I | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV99666059, COSV99666894; called by muse, mutect2, varscan2
- ATXN7L3 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101231725; called by muse, mutect2, varscan2
- C8A | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as COSV100776441; called by muse, mutect2, varscan2
- CAB39L | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 64/86 reads (74%) | catalogued as COSV61714780; called by muse, mutect2, varscan2
- CAVIN2 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100414037, COSV58423264; called by muse, mutect2, varscan2
- CDH2 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52283268, COSV52285516, COSV99295737; called by muse, mutect2, varscan2
- CDH9 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1163327293, COSV99141735; called by muse, mutect2, varscan2
- CENPI | c.2221C>T p.H741Y | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV99515035; called by muse, mutect2, varscan2
- CEP126 | c.1148G>T p.C383F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1052558937, COSV54825317, COSV99680586; called by muse, mutect2, varscan2
- CEP85L | c.1706A>T p.Q569L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100874059; called by muse, mutect2, varscan2
- CFAP20DC | c.2084A>G p.H695R (on ENST00000482387 / NM_001351530.2; = p.H444R on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs1429235543, COSV99918089; called by muse, mutect2, varscan2
- CNKSR2 | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101069865; called by muse, mutect2, varscan2
- COL11A1 | c.2755-2A>T p.X919_splice | Splice Site (SNP) | VAF 25/56 reads (45%) | catalogued as COSV62185975; called by muse, mutect2, varscan2
- COL11A1 | c.2741C>A p.P914H | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV100615208; called by muse, mutect2, varscan2
- COL11A1 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV100615209; called by muse, mutect2, varscan2
- COL18A1 | c.3435C>A p.G1145= (on ENST00000359759 / NM_130444.3; = p.G910= on NM_030582.4) | Splice Region (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100644977, COSV60588055; called by muse, varscan2
- COLGALT1 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99394846, COSV99395194; called by muse, mutect2, varscan2
- CRHR2 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.303); catalogued as COSV100529701; called by muse, mutect2, varscan2
- CSH2 | c.457-2A>T p.X153_splice | Splice Site (SNP) | VAF 48/120 reads (40%) | catalogued as COSV100400147; called by muse, mutect2, varscan2
- CSMD3 | c.10222+1G>T p.X3408_splice (on ENST00000297405 / NM_001363185.1; = p.X3239_splice on NM_052900.3) | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52164199, COSV52192720; called by muse, mutect2
- CTNNA2 | c.2512A>T p.T838S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.065); catalogued as COSV100559513; called by muse, mutect2, varscan2
- CTNND2 | c.2785A>G p.I929V | Missense Mutation (SNP) | VAF 150/266 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs746104096, COSV100472068; called by muse, mutect2, varscan2
- CUBN | c.4967C>G p.P1656R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100912068; called by muse, mutect2, varscan2
- CUBN | c.4759G>T p.A1587S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100912069; called by muse, mutect2, varscan2
- CUBN | c.390T>A p.T130= | Splice Region (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100910532; called by muse, mutect2, varscan2
- CYP27A1 | c.653G>T p.C218F | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99298341; called by muse, mutect2, varscan2
- CYTIP | c.812G>T p.R271M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV99938627; called by muse, mutect2, varscan2
- DCAF4L2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60477129; called by muse, mutect2, varscan2
- DCC | c.2317C>A p.R773S | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as rs1446168229, COSV100498270, COSV59081935; called by muse, mutect2, varscan2
- DCDC1 | c.3925T>C p.C1309R (on ENST00000597505 / NM_001367979.1; = p.C416R on NM_020869.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV100337854, COSV58000359; called by muse, mutect2, varscan2
- DCDC1 | c.2410C>A p.H804N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); catalogued as COSV100662746; called by muse, mutect2, varscan2
- DDX18 | c.1354G>T p.V452F | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54305267, COSV99604330; called by muse, mutect2, varscan2
- DHX16 | c.1987A>T p.T663S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100905133; called by muse, mutect2, varscan2
- DMD | c.5725G>T p.E1909* | Nonsense Mutation (SNP) | VAF 26/38 reads (68%) | catalogued as CM098426, COSV100818169; called by muse, mutect2, varscan2
- DNAH8 | c.7582C>A p.P2528T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543380; called by muse, mutect2, varscan2
- DNAH8 | c.11600C>A p.S3867Y | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100543381, COSV59432925; called by muse, mutect2, varscan2
- DOCK9 | c.1874T>A p.V625E (on ENST00000376460 / NM_001366676.2; = p.V626E on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/150 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.312); catalogued as COSV100238008; called by muse, mutect2, varscan2
- DPP10 | c.1252C>A p.L418M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100059040, COSV100067167; called by muse, mutect2, varscan2
- DUOX2 | c.1036A>T p.M346L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs573609412, COSV100545749; called by muse, mutect2, varscan2
- DYSF | c.6058C>A p.R2020S | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370286628, COSV99244446; called by muse, mutect2, varscan2
- EFEMP2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.595); catalogued as rs148940436; called by muse, mutect2, varscan2
- EMX2 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV101463576; called by muse, mutect2, varscan2
- ENPP7 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100093202; called by muse, mutect2, varscan2
- EPB41L3 | c.1942T>A p.F648I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.915); catalogued as COSV100548200; called by muse, mutect2, varscan2
- ERCC6L2 | c.1158+1G>A p.X386_splice | Splice Site (SNP) | VAF 27/68 reads (40%) | catalogued as COSV99998287; called by muse, mutect2, varscan2
- ERN2 | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV99890582; called by muse, mutect2, varscan2
- ESPL1 | c.5054G>T p.G1685V | Missense Mutation (SNP) | VAF 55/70 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99228917; called by muse, mutect2, varscan2
- EVA1A | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99285307; called by muse, mutect2, varscan2
- EYS | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as COSV100675678; called by muse, mutect2, varscan2
- FAM136A | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1277340338, COSV99231883; called by muse, mutect2, varscan2
- FAM241B | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as rs201072929, COSV100958385, COSV100958387; called by muse, mutect2, varscan2
- FAM47C | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV100792281, COSV63727724; called by muse, mutect2, varscan2
- FAN1 | c.2090_2091del p.R697Nfs*5 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs777432497; called by pindel, varscan2
- FCGBP | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1304415363; called by muse, mutect2, varscan2
- FKRP | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100586647; called by mutect2, varscan2
- FLG | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 176/422 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1220069584, COSV64245113; called by muse, mutect2, varscan2
- FLI1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754322278, COSV61378190; called by muse, mutect2, varscan2
- FN1 | c.4565C>A p.T1522N | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); catalogued as COSV100116113; called by muse, mutect2, varscan2
- FN1 | c.2906del p.P969Lfs*12 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | catalogued as CM164416; called by mutect2, pindel, varscan2
- FNDC1 | c.5172G>T p.T1724= | Splice Region (SNP) | VAF 54/129 reads (42%) | catalogued as COSV51937393, COSV99794955; called by muse, mutect2, varscan2
- FSTL5 | c.267T>A p.C89* | Nonsense Mutation (SNP) | VAF 13/19 reads (68%) | catalogued as COSV100052873; called by muse, mutect2, varscan2
- FUT9 | c.399G>C p.W133C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100133088, COSV56157429; called by muse, mutect2, varscan2
- FUT9 | c.524C>G p.T175R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.093); catalogued as COSV100133089; called by muse, mutect2, varscan2
- GABRA2 | c.1127C>G p.P376R | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100733842, COSV100734631; called by muse, mutect2, varscan2
- GLYAT | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774121411, COSV99557124; called by muse, mutect2, varscan2
- GPHN | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100015416; called by muse, mutect2, varscan2
- GPR158 | c.2199G>T p.M733I | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893600, COSV66276621; called by muse, mutect2, varscan2
- GPR50 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 166/513 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV54440350, COSV99505669; called by muse, mutect2, varscan2
- GPRASP1 | c.3316C>G p.Q1106E | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.535); catalogued as COSV100850908, COSV64356463; called by muse, mutect2, varscan2
- GRM1 | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.342); catalogued as COSV99264125; called by muse, mutect2, varscan2
- HCRTR2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs763684995, COSV100904169; called by muse, mutect2, varscan2
- HHIPL1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs771618810, COSV100414979; called by muse, mutect2, varscan2
- HPSE2 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV100985009; called by muse, mutect2, varscan2
- HSP90AB1 | c.1717A>T p.K573* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100806942; called by muse, mutect2, varscan2
- IFT57 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99197235; called by muse, mutect2, varscan2
- INSC | c.1471G>C p.A491P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101088780; called by muse, mutect2, varscan2
- INTS7 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100877386; called by muse, mutect2, varscan2
- IQUB | c.2262G>T p.Q754H | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100226757; called by muse, mutect2, varscan2
- IRS4 | c.2229C>G p.Y743* | Nonsense Mutation (SNP) | VAF 51/138 reads (37%) | catalogued as COSV100929428; called by muse, mutect2, varscan2
- ITIH3 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV99834943, COSV99835659; called by muse, varscan2
- ITPRID2 | c.2843C>G p.S948* | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as COSV100237891, COSV57469709; called by muse, mutect2, varscan2
- JMJD1C | c.6850A>T p.S2284C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1260844225, COSV100550148; called by muse, mutect2, varscan2
- KARS1 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as rs779473612, COSV100093723; called by muse, mutect2, varscan2
- KAT7 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV99371598; called by muse, mutect2, varscan2
- KCNA3 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100871198; called by muse, mutect2, varscan2
- KHK | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV53149376; called by muse, mutect2, varscan2
- KIF1A | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100239871; called by muse, mutect2, varscan2
- KLHL1 | c.2064G>T p.M688I | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1042309602, COSV99060880; called by muse, mutect2, varscan2
- KLHL4 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.556); catalogued as COSV100909141; called by muse, mutect2, varscan2
- KLK9 | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99143883; called by muse, mutect2, varscan2
- KNSTRN | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1438983381; called by muse, mutect2
- KRTAP5-3 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV101294489; called by muse, varscan2
- KRTAP5-3 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV101294490; called by muse, varscan2
- LAMA2 | c.568T>C p.S190P | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1455111347, COSV101370083; called by muse, varscan2
- LCN1 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99704335; called by muse, mutect2, varscan2
- LONRF1 | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs201800084, COSV101238174; called by muse, mutect2, varscan2
- LRGUK | c.1623G>C p.E541D | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV53641578, COSV99603733; called by muse, mutect2, varscan2
- LRP1B | c.1320C>A p.N440K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV101252825, COSV104431590; called by muse, mutect2, varscan2
- LRP2 | c.8524T>C p.C2842R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99786591; called by muse, mutect2, varscan2
- LRRC4C | c.330C>A p.N110K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537026; called by muse, mutect2, varscan2
- MAGEC1 | c.2492T>A p.V831E | Missense Mutation (SNP) | VAF 136/333 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1222927541, COSV99594864; called by muse, mutect2, varscan2
- MAP2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs939642131, COSV52293254; called by muse, mutect2, varscan2
- MAP3K19 | c.3263T>C p.V1088A | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100208081; called by muse, mutect2, varscan2
- MAP7D3 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV100286182; called by muse, mutect2, varscan2
- MAPRE2 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV100290270; called by muse, mutect2, varscan2
- MDGA2 | c.2741del p.G914Dfs*4 (on ENST00000399232 / NM_001113498.2; = p.G616Dfs*4 on NM_182830.4) | Frame Shift Del (DEL) | VAF 34/65 reads (52%) | catalogued as COSV100637351; called by mutect2, pindel, varscan2
- MERTK | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99774089; called by muse, mutect2, varscan2
- MGMT | c.485G>C p.G162A (on ENST00000306010; = p.G131A on NM_002412.5) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100022399; called by muse, mutect2, varscan2
- MICB | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99357318; called by muse, mutect2, varscan2
- MID2 | c.758G>C p.R253P | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99464048; called by muse, mutect2, varscan2
- MINAR1 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100548641; called by muse, mutect2, varscan2
- MKI67 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64073717; called by muse, mutect2, varscan2
- MS4A14 | c.1084T>A p.S362T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.103); catalogued as COSV100280070; called by muse, mutect2, varscan2
- MUC16 | c.23086G>A p.V7696M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs770085186, COSV101198328, COSV67474468; called by muse, mutect2, varscan2
- MUSK | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503646; called by muse, mutect2, varscan2
- MYH1 | c.5752G>A p.E1918K | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99874944; called by muse, mutect2, varscan2
- MYH7 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1566527832, COSV62524598; ClinVar: uncertain significance; called by mutect2, varscan2
- MYH8 | c.3854C>G p.T1285R | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV101238199; called by muse, mutect2, varscan2
- MYOM1 | c.2557G>T p.G853* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | catalogued as COSV99865305; called by muse, mutect2, varscan2
- NALCN | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV51942639, COSV99213054; called by muse, mutect2, varscan2
- NBAS | c.380T>A p.V127D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99867297; called by muse, mutect2
- NCKAP1 | c.2165G>T p.G722V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV100719991; called by muse, mutect2, varscan2
- NDN | c.624C>G p.S208R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100086233, COSV59358388, COSV59359664; called by muse, mutect2, varscan2
- NKRF | c.1406T>A p.V469D | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as COSV100441426; called by muse, mutect2, varscan2
- NLRP14 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 38/100 reads (38%) | catalogued as COSV100204567; called by muse, mutect2, varscan2
- NOX1 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99471419, COSV99471702; called by muse, mutect2, varscan2
- NTF3 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 103/154 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58417921; called by muse, mutect2, varscan2
- ODAM | c.810+2T>C p.X270_splice | Splice Site (SNP) | VAF 15/25 reads (60%) | catalogued as COSV101258027; called by muse, mutect2, varscan2
- OPRD1 | c.300C>G p.S100R | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV99330069; called by muse, mutect2, varscan2
- OR11L1 | c.700_701insT p.R234Lfs*36 | Frame Shift Ins (INS) | VAF 16/79 reads (20%) | catalogued as COSV100869387; called by mutect2, pindel, varscan2
- OR1Q1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs749123312, COSV99939174; called by muse, mutect2, varscan2
- OR4A5 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV60521479; called by muse, mutect2, varscan2
- OR4K5 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 79/123 reads (64%) | catalogued as COSV60003639; called by muse, mutect2, varscan2
- OR52E4 | c.82T>A p.W28R | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100389146; called by muse, mutect2, varscan2
- OR5L1 | c.613T>A p.L205M | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100449919; called by muse, mutect2, varscan2
- OR8K3 | c.462C>A p.F154L | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as rs779569425, COSV100449660; called by muse, mutect2, varscan2
- OR8K5 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.951); catalogued as COSV100537150; called by muse, varscan2
- OR9G4 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV100265001; called by muse, mutect2, varscan2
- OSTN | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs932591911, COSV100174143; called by muse, mutect2, varscan2
- OTOA | c.2339C>T p.T780I (on ENST00000286149; = p.T766I on NM_144672.4) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53754729, COSV99623615; called by muse, mutect2, varscan2
- OTUD7B | c.1790G>A p.S597N | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100967358; called by muse, mutect2, varscan2
- PABPC5 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100442124; called by muse, mutect2, varscan2
- PAPPA2 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100868379, COSV62798918; called by muse, mutect2, varscan2
- PARP11 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99958730; called by muse, mutect2, varscan2
- PCDHGB6 | c.484A>T p.I162L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.292); catalogued as COSV99530998; called by muse, mutect2, varscan2
- PCGF5 | c.439C>G p.R147G | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100277524; called by muse, mutect2, varscan2
- PCSK7 | c.1128T>G p.S376R | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100309198; called by muse, mutect2, varscan2
- PDE4D | c.1048A>T p.T350S (on ENST00000340635 / NM_001104631.2; = p.T214S on NM_006203.4) | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as COSV100401373; called by muse, mutect2, varscan2
- PDHA2 | c.821del p.G274Efs*6 | Frame Shift Del (DEL) | VAF 35/64 reads (55%) | catalogued as COSV99756953; called by mutect2, pindel, varscan2
- PDILT | c.648C>G p.H216Q | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV99043641; called by muse, mutect2, varscan2
- PEG3 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55636113, COSV99687372; called by muse, mutect2, varscan2
- PFKL | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs755851304, COSV62462897; called by muse, mutect2, varscan2
- PIK3C2G | c.3212G>T p.G1071V (on ENST00000676171; = p.G1030V on NM_004570.5) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849642; called by muse, mutect2, varscan2
- PITPNM3 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99337920; called by muse, mutect2, varscan2
- PIWIL3 | c.2376G>T p.R792S | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100177353; called by muse, mutect2, varscan2
- PKHD1L1 | c.9035C>T p.P3012L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV101005417, COSV65755136; called by muse, mutect2, varscan2
- PLXNA4 | c.4933C>G p.L1645V | Missense Mutation (SNP) | VAF 93/147 reads (63%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.877); catalogued as COSV100322534; called by muse, mutect2, varscan2
- POM121L12 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV101374844, COSV68693074; called by muse, mutect2, varscan2
- PRAMEF1 | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.552); catalogued as rs149382773, COSV100179428; called by muse, mutect2, varscan2
- PRAMEF19 | c.1341del p.N448Tfs*? | Frame Shift Del (DEL) | VAF 76/292 reads (26%) | catalogued as COSV65818644; called by pindel, varscan2
- PRAMEF2 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 179/461 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99534816; called by muse, mutect2, varscan2
- PRKACB | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100853894; called by muse, mutect2, varscan2
- PRKAR1A | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV100675077; called by muse, mutect2, varscan2
- PRKD1 | c.2650C>A p.L884M | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); catalogued as COSV100119317; called by muse, mutect2, varscan2
- PRKDC | c.11098G>T p.E3700* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100038497; called by muse, mutect2, varscan2
- PTGER3 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV100138255; called by muse, mutect2, varscan2
- PTPRD | c.3040C>A p.L1014M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100643397; called by muse, mutect2, varscan2
- PTPRK | c.2167A>T p.T723S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV100950413; called by muse, mutect2, varscan2
- RALGAPA1 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.37); catalogued as COSV99353344; called by muse, mutect2, varscan2
- RAP1GDS1 | c.827A>T p.Q276L (on ENST00000408927 / NM_001100427.2; = p.Q277L on NM_021159.5) | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV99216704; called by muse, mutect2, varscan2
- RB1 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 57/73 reads (78%) | catalogued as COSV57297755; called by muse, mutect2, varscan2
- RBM4 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs765301901, COSV59518195; called by muse, mutect2, varscan2
- RNASEL | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100842543; called by muse, mutect2, varscan2
- RP1 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99606300; called by muse, mutect2, varscan2
- RP1 | c.5575C>G p.Q1859E | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs1371195142, COSV99606301, COSV99606666; called by muse, mutect2, varscan2
- SCN3A | c.5024C>G p.S1675C | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99325700; called by muse, mutect2, varscan2
- SELE | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1340887469, COSV100324502; called by muse, mutect2, varscan2
- SERPINA9 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs561114629, COSV100097902; called by muse, varscan2
- SHROOM3 | c.1286A>G p.E429G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99933556; called by muse, mutect2, varscan2
- SHROOM4 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56799157, COSV99173007; called by muse, mutect2, varscan2
- SI | c.2972C>A p.S991* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100014075; called by muse, mutect2, varscan2
- SI | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.13); catalogued as COSV100014078; called by muse, mutect2, varscan2
- SIPA1L1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV62168669; called by muse, mutect2, varscan2
- SLC18A1 | c.1220A>T p.D407V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368321; called by mutect2, varscan2
- SLC4A10 | c.1676G>T p.G559V (on ENST00000446997 / NM_001354461.2; = p.G529V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99762550; called by muse, mutect2, varscan2
- SLC4A1AP | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100389172; called by muse, mutect2, varscan2
- SLC4A5 | c.3193G>T p.D1065Y | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100697407, COSV61027834; called by muse, mutect2, varscan2
- SLITRK2 | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100157335, COSV59423963; called by muse, mutect2, varscan2
- SMCHD1 | c.4869G>C p.M1623I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV99860656; called by muse, mutect2, varscan2
- SMR3A | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV99895506; called by muse, mutect2, varscan2
- SNX17 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as COSV99277277; called by muse, mutect2, varscan2
- SORCS1 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99543455; called by muse, mutect2, varscan2
- SORCS3 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV100864561; called by muse, mutect2, varscan2
- SPANXN2 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100979792; called by muse, mutect2, varscan2
- SPEF2 | c.827C>A p.T276K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as COSV99213683; called by muse, varscan2
- SPEF2 | c.3026C>A p.S1009* | Nonsense Mutation (SNP) | VAF 107/177 reads (60%) | catalogued as COSV100606355; called by muse, mutect2, varscan2
- SPTA1 | c.5878C>A p.L1960I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63759488; called by muse, mutect2, varscan2
- SPTA1 | c.134G>T p.R45M | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as CM951193, COSV100934282; called by muse, mutect2, varscan2
- SPTBN5 | c.6476C>T p.T2159I | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV100310686; called by muse, mutect2, varscan2
- SRCAP | c.7996G>T p.E2666* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV52681332, COSV99349314; called by muse, mutect2, varscan2
- STX11 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100845463; called by muse, mutect2, varscan2
- SYTL4 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV52170194, COSV99342653; called by muse, mutect2, varscan2
- TAS2R13 | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 77/110 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953459143, COSV101183711; called by muse, mutect2, varscan2
- TECTA | c.5178G>T p.K1726N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs370060581; called by muse, mutect2, varscan2
- TEX13A | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100780742; called by muse, mutect2, varscan2
- THOC2 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55540262; called by muse, mutect2, varscan2
- TMTC3 | c.2054A>T p.N685I | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99898101; called by muse, mutect2, varscan2
- TRA2B | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.129); catalogued as COSV99373169; called by muse, mutect2, varscan2
- TRIM68 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs368773254; called by muse, mutect2, varscan2
- TRPM6 | c.5304G>T p.Q1768H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100665396; called by muse, mutect2, varscan2
- TTC13 | c.2309+1G>A p.X770_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100792851; called by muse, mutect2, varscan2
- TTN | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV100594876, COSV59962815; called by muse, mutect2, varscan2
- TXNDC5 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.3); catalogued as rs763092237, COSV99306349; called by muse, mutect2, varscan2
- UBR5 | c.5463C>G p.Y1821* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV99639427; called by muse, mutect2, varscan2
- UGT2A1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99683843; called by muse, mutect2, varscan2
- UNC13A | c.1227C>A p.D409E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99407148; called by muse, mutect2, varscan2
- UNC13C | c.3910G>T p.E1304* | Nonsense Mutation (SNP) | VAF 64/152 reads (42%) | catalogued as COSV52841660, COSV52857081; called by muse, mutect2, varscan2
- UNC45B | c.815A>G p.K272R | Missense Mutation (SNP) | VAF 139/399 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as COSV99268214; called by muse, mutect2, varscan2
- UNC5D | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV54818603, COSV99772300; called by muse, mutect2, varscan2
- USH2A | c.8725G>C p.G2909R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100229215, COSV56410669; called by muse, mutect2, varscan2
- USP10 | c.1430T>G p.V477G | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV99551138; called by muse, mutect2, varscan2
- VTA1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as COSV100859174; called by muse, mutect2, varscan2
- VWA7 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 37/59 reads (63%) | catalogued as COSV100791782; called by muse, varscan2
- WDR44 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.018); catalogued as rs866057234, COSV99561190; called by muse, mutect2, varscan2
- XIRP2 | c.7678C>A p.Q2560K (on ENST00000628543; = p.Q2735K on NM_152381.6) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV99738672; called by muse, mutect2, varscan2
- ZBTB33 | c.1096A>T p.S366C | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV100434052; called by muse, mutect2, varscan2
- ZFP91 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as rs775298121, COSV100284320, COSV60157798; called by muse, mutect2, varscan2
- ZIM3 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1031472257, COSV99517649; called by muse, mutect2, varscan2
- ZNF107 | c.2166T>G p.C722W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100788221; called by muse, mutect2, varscan2
- ZNF273 | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs1311792635, COSV100139148; called by muse, mutect2, varscan2
- ZNF37A | c.1675T>G p.Y559D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV100697273; called by muse, mutect2, varscan2
- ZNF618 | c.532G>T p.E178* (on ENST00000374126 / NM_001318042.2; = p.E146* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 29/121 reads (24%) | catalogued as COSV99929268; called by muse, mutect2, varscan2
- ZNF630 | c.968A>T p.K323M | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99332216; called by muse, mutect2, varscan2
- ZNF641 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 76/91 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1166846277, COSV99973352; called by muse, mutect2, varscan2
- ZNF764 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV99410948; called by muse, mutect2, varscan2
- ZNF883 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as rs780069609, COSV101432521; called by muse, mutect2, varscan2
- ZSCAN21 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 82/129 reads (64%) | SIFT tolerated (0.65); PolyPhen benign (0.101); catalogued as COSV99460638; called by muse, mutect2, varscan2
- ZW10 | c.1435A>G p.I479V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV99562465; called by muse, mutect2, varscan2
- ADGRB3 | c.4357dup p.D1453Gfs*26 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- AK5 | c.96del p.D33Ifs*3 (on ENST00000354567 / NM_174858.3; = p.D7Ifs*3 on NM_012093.4) | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- COPS2 | c.1140_1154del p.I380_V385delinsM | In Frame Del (DEL) | VAF 15/136 reads (11%) | called by mutect2, pindel
- DSP | c.1194dup p.I399Hfs*32 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- FAT1 | c.3990del p.N1330Kfs*38 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | called by mutect2, pindel, varscan2
- FRG2C | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HAPLN4 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- IGHV6-1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- IGKV1D-43 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- MAS1 | c.131del p.P44Qfs*18 | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591dup p.M1531Nfs*4 | Frame Shift Ins (INS) | VAF 9/15 reads (60%) | called by mutect2, varscan2
- PTH2R | c.579del p.S193Rfs*8 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- RBP3 | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- SPATA31A3 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.351); called by mutect2, varscan2
- TBC1D10A | c.1088_1090del p.R363_E364delinsQ | In Frame Del (DEL) | VAF 22/34 reads (65%) | called by pindel, varscan2
- THAP11 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.31); PolyPhen benign (0.23); called by muse, mutect2
- VN1R5 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZMYM3 | c.1635dup p.C546Lfs*10 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- ZNF99 | c.1544del p.G515Afs*15 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- ACKR3 | c.666C>T p.A222= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as rs748314078, COSV56020862; called by muse, mutect2, varscan2
- ACOT4 | c.562C>T p.L188= | Silent (SNP) | VAF 50/72 reads (69%) | catalogued as COSV100412779; called by muse, mutect2, varscan2
- APC | c.3924A>G p.K1308= | Silent (SNP) | VAF 31/36 reads (86%) | catalogued as CD096080, CD972006, COSV99965350; called by muse, mutect2, varscan2
- ASB1 | c.231C>T p.L77= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99223118; called by muse, mutect2, varscan2
- CAPN10 | c.1108C>A p.R370= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV99549959; called by muse, mutect2, varscan2
- CCN3 | c.525A>T p.P175= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV99422725; called by muse, mutect2, varscan2
- CFAP206 | c.700C>A p.R234= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs140079201, COSV99739154; called by muse, mutect2, varscan2
- CIB3 | c.375G>T p.A125= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV54165810, COSV99521699; called by muse, mutect2, varscan2
- COL27A1 | c.5364C>T p.F1788= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV100620736; called by muse, mutect2, varscan2
- DCAF8L1 | c.1425C>T p.F475= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV101491389; called by muse, mutect2, varscan2
- DIRAS3 | c.66C>T p.A22= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV100921300; called by muse, mutect2, varscan2
- DOCK2 | c.3555G>A p.L1185= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV99910403; called by muse, mutect2, varscan2
- ELOA2 | c.1380A>G p.S460= | Silent (SNP) | VAF 104/180 reads (58%) | catalogued as rs777675135, COSV99795945; called by muse, mutect2, varscan2
- ENPP4 | c.976C>T p.L326= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100320238; called by muse, mutect2, varscan2
- ETS1 | c.105A>T p.P35= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs765144107, COSV100090068; called by muse, mutect2, varscan2
- FAM210A | c.234A>T p.P78= | Silent (SNP) | VAF 61/173 reads (35%) | catalogued as COSV100452265; called by muse, mutect2, varscan2
- FAM234B | c.1386T>A p.G462= | Silent (SNP) | VAF 98/374 reads (26%) | catalogued as COSV99545386; called by muse, mutect2, varscan2
- FBXO4 | c.984A>G p.L328= | Silent (SNP) | VAF 57/211 reads (27%) | catalogued as COSV99715043; called by muse, mutect2, varscan2
- FBXW2 | c.360G>A p.K120= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV100535085; called by muse, mutect2, varscan2
- GPR45 | c.663G>A p.T221= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs141451236; called by muse, mutect2, varscan2
- GRIA4 | c.1807C>T p.L603= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99229065; called by muse, mutect2, varscan2
- GRIN2A | c.3633C>T p.S1211= | Silent (SNP) | VAF 215/389 reads (55%) | catalogued as COSV100408393; called by muse, mutect2, varscan2
- HDAC4 | c.2076G>A p.T692= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs993038179, COSV100612697; called by muse, mutect2, varscan2
- HMGB4 | c.153C>A p.S51= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV99586209; called by muse, mutect2, varscan2
- IL27RA | c.1818C>A p.T606= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99651894; called by muse, mutect2, varscan2
- ILDR2 | c.226C>A p.R76= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs748472038, COSV99613248; called by muse, mutect2, varscan2
- ITPR2 | c.6834G>T p.L2278= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV101189817; called by muse, mutect2, varscan2
- KCNH7 | c.1608C>A p.R536= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs766180381, COSV100034184; called by muse, mutect2, varscan2
- KIF19 | c.1869G>T p.L623= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100738951; called by muse, mutect2, varscan2
- KIRREL3 | c.486G>A p.A162= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs753719353, COSV73104930; called by muse, mutect2, varscan2
- KLHL34 | c.1158C>T p.D386= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV101069866, COSV99058759; called by muse, mutect2, varscan2
- KLK8 | c.312C>T p.I104= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as COSV51594529; called by muse, mutect2, varscan2
- KNG1 | c.834G>T p.L278= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV99405124; called by muse, mutect2
- KRTAP10-3 | c.303G>A p.V101= | Silent (SNP) | VAF 76/213 reads (36%) | catalogued as COSV100551937, COSV59974286; called by muse, mutect2, varscan2
- LCE2B | c.217C>T p.L73= | Silent (SNP) | VAF 105/230 reads (46%) | catalogued as rs768951534, COSV100909279; called by muse, mutect2, varscan2
- LRP2 | c.8277C>A p.R2759= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99786593; called by muse, mutect2, varscan2
- LTB4R | c.510G>T p.P170= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as COSV99350484; called by muse, mutect2, varscan2
- LYPD2 | c.105G>T p.S35= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV100820945; called by muse, mutect2, varscan2
- MAGEC1 | c.2946C>A p.L982= | Silent (SNP) | VAF 76/208 reads (37%) | catalogued as COSV53582038, COSV99594866; called by muse, mutect2, varscan2
- MAST1 | c.498C>T p.R166= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV99262334; called by muse, mutect2, varscan2
- MIEF1 | c.1179C>T p.A393= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs1343649217, COSV100307532; called by muse, mutect2, varscan2
- MLPH | c.1287G>T p.P429= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99221809; called by muse, mutect2, varscan2
- MYO7A | c.1053G>C p.S351= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV101289045; called by muse, mutect2, varscan2
- NEXMIF | c.1155C>A p.G385= | Silent (SNP) | VAF 55/222 reads (25%) | catalogued as COSV99279686; called by muse, mutect2, varscan2
- NLRP3 | c.2514A>G p.T838= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs765285010, COSV100275275; called by muse, mutect2, varscan2
- OR10C1 | c.552T>A p.P184= (on ENST00000622521; = p.P182= on NM_013941.3) | Silent (SNP) | VAF 64/237 reads (27%) | catalogued as COSV101010789; called by muse, mutect2, varscan2
- OR11H12 | c.294C>G p.V98= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV101612458, COSV101612473; called by mutect2, varscan2
- OR14C36 | c.714C>G p.T238= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100507384; called by muse, mutect2, varscan2
- OR14J1 | c.408C>G p.P136= | Silent (SNP) | VAF 61/201 reads (30%) | catalogued as COSV101012713; called by muse, mutect2, varscan2
- OR1B1 | c.174C>T p.H58= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100506410; called by muse, mutect2, varscan2
- OR6K2 | c.786C>T p.R262= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100656691; called by muse, mutect2, varscan2
- OR8B12 | c.363C>G p.R121= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100172643; called by muse, mutect2, varscan2
- OR8K5 | c.432G>C p.L144= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV100537151; called by muse, varscan2
- PASD1 | c.144G>C p.L48= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100949093; called by muse, mutect2, varscan2
- PASD1 | c.496C>A p.R166= | Silent (SNP) | VAF 64/172 reads (37%) | catalogued as rs750457198, COSV100949094; called by muse, varscan2
- PASD1 | c.1320G>T p.G440= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as COSV100949096; called by muse, varscan2
- PCDHA2 | c.1944C>T p.L648= | Silent (SNP) | VAF 51/68 reads (75%) | catalogued as rs140366950; called by muse, mutect2, varscan2
- PER1 | c.3762C>T p.A1254= | Silent (SNP) | VAF 133/198 reads (67%) | catalogued as COSV100424270; called by muse, mutect2, varscan2
- PKHD1 | c.12033G>A p.L4011= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV100943708; called by muse, mutect2, varscan2
- PLPBP | c.313T>C p.L105= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as COSV100065540; called by muse, mutect2, varscan2
- PLPPR3 | c.1539C>T p.A513= (on ENST00000520876 / NM_001270366.2; = p.A541= on NM_024888.2) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100608360; called by muse, mutect2, varscan2
- RAPGEF2 | c.3399C>T p.P1133= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV100030547; called by muse, mutect2, varscan2
- RHOXF2B | c.219C>A p.G73= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs782311543, COSV101003941; called by muse, mutect2, varscan2
- RUNX1T1 | c.972G>A p.R324= (on ENST00000265814 / NM_001198628.1; = p.R297= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/174 reads (32%) | catalogued as COSV56142909, COSV99749565; called by muse, varscan2
- RXFP3 | c.1023C>A p.P341= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV100347308; called by muse, mutect2, varscan2
- RYR2 | c.11820G>T p.L3940= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100768070; called by muse, mutect2, varscan2
- SERINC5 | c.96C>G p.S32= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV101549050; called by muse, mutect2, varscan2
- SI | c.5130C>T p.L1710= | Silent (SNP) | VAF 57/75 reads (76%) | catalogued as COSV100014069; called by muse, mutect2, varscan2
- SLC16A7 | c.843G>T p.S281= | Silent (SNP) | VAF 79/95 reads (83%) | catalogued as COSV53892256; called by muse, mutect2, varscan2
- SLC4A11 | c.1626C>T p.A542= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1247924686, COSV101195895; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A9 | c.1167G>T p.T389= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99195201; called by muse, mutect2, varscan2
- SPAG9 | c.1875G>A p.K625= (on ENST00000262013 / NM_001130528.3; = p.K611= on NM_003971.6) | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100004509; called by muse, mutect2, varscan2
- SRGAP1 | c.1167T>C p.D389= | Silent (SNP) | VAF 40/52 reads (77%) | catalogued as COSV100754265; called by muse, varscan2
- STK32B | c.693G>A p.T231= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1253398023, COSV51480354, COSV99284729; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2643A>G p.P881= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs1204872827, COSV100561488; called by muse, mutect2, varscan2
- TAF9B | c.433C>A p.R145= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV100540559; called by muse, mutect2, varscan2
- TCN1 | c.1047T>C p.N349= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs976172709, COSV57252745; called by muse, mutect2, varscan2
- TMC2 | c.1128C>T p.F376= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100727358; called by muse, mutect2, varscan2
- TPTE | c.150C>A p.A50= | Silent (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- TRIM22 | c.1290G>A p.K430= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as COSV101181201; called by muse, mutect2, varscan2
- TRIM39 | c.120C>T p.V40= | Silent (SNP) | VAF 145/266 reads (55%) | catalogued as COSV100935633; called by muse, mutect2, varscan2
- TSKS | c.1416G>A p.L472= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV99882929; called by muse, mutect2, varscan2
- TUBB8 | c.540G>T p.V180= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV100225922; called by muse, mutect2, varscan2
- TUBGCP2 | c.1197C>T p.I399= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53309289; called by muse, mutect2, varscan2
- VEPH1 | c.555A>G p.L185= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as COSV100747386; called by muse, mutect2, varscan2
- XIRP1 | c.1197G>T p.V399= | Silent (SNP) | VAF 60/116 reads (52%) | catalogued as COSV100453393; called by muse, mutect2, varscan2
- ZBTB16 | c.1318C>A p.R440= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100250958; called by muse, mutect2, varscan2
- ZSWIM5 | c.1729C>T p.L577= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV100655348; called by muse, mutect2, varscan2
- CTSL3P | n.492A>G | RNA (SNP) | VAF 28/69 reads (41%) | catalogued as rs772703694; called by muse, mutect2, varscan2
- DCHS2 | n.5823C>A | RNA (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100601103, COSV61778342; called by muse, mutect2, varscan2
- MMP16 | c.1222+5084G>T | Intron (SNP) | VAF 31/85 reads (36%) | catalogued as COSV99686111; called by muse, mutect2, varscan2
- MRPS17P9 | n.86G>C | RNA (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- RABGGTB | c.111+303A>G | Intron (SNP) | VAF 14/40 reads (35%) | catalogued as rs1384955779, COSV100174922; called by muse, mutect2, varscan2
- SEC14L1 | c.-240+160G>A | Intron (SNP) | VAF 43/105 reads (41%) | catalogued as COSV100811344; called by muse, mutect2, varscan2
- SNORD116-12 | n.34G>T | RNA (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-1G>T | 5'UTR (SNP) | VAF 43/79 reads (54%) | catalogued as COSV100129311; called by muse, mutect2, varscan2
- TTN | c.10360+3363C>A | Intron (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100594874, COSV60087929; called by muse, mutect2, varscan2
- VPS26C | chr21:37221290 C>A | 3'Flank (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- ZNF702P | n.1818A>G | RNA (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
